Somatic mutation profile of tumor specimen 0DU81E from CCDI case PBCKKP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 13.3 years (4,845 days).
Specimen 0DU81E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 728bd1a6-9a35-40e0-a060-3b85ccf7636d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU809 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/320daeba-c8af-4a5d-92f8-43c83b735b3a

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 269/531 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 602/654 reads (92%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, varscan2
- ATRX | c.3064C>T p.R1022* | Nonsense Mutation (SNP) | VAF 188/204 reads (92%) | catalogued as COSV64870666; called by muse, varscan2
- CCNP | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 344/749 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772979117; called by muse, varscan2
- MTFR1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 178/463 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV50952162; called by muse, varscan2
- POTEE | c.1922A>G p.E641G | Missense Mutation (SNP) | VAF 310/663 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV58233075; called by muse, varscan2
- ARID1B | c.10_13del p.N4Rfs*65 | Frame Shift Del (DEL) | VAF 78/615 reads (13%) | called by pindel, varscan2
- CABIN1 | c.5087del p.P1696Lfs*107 | Frame Shift Del (DEL) | VAF 396/1230 reads (32%) | called by pindel, varscan2
- DAB2 | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 328/752 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- DGKD | c.1871T>C p.I624T (on ENST00000264057 / NM_152879.3; = p.I580T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/522 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- KLHL17 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 104/582 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- MGA | c.8252T>G p.M2751R (on ENST00000219905 / NM_001164273.1; = p.M2542R on NM_001080541.2) | Missense Mutation (SNP) | VAF 173/387 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, varscan2
- POLH | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 64/428 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- SYT10 | c.428A>G p.E143G | Missense Mutation (SNP) | VAF 332/750 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by muse, varscan2
- TFPI2 | c.638A>T p.K213I | Missense Mutation (SNP) | VAF 140/422 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, varscan2
- ZCCHC18 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 180/228 reads (79%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, varscan2
- ZNF557 | c.145G>T p.E49* (on ENST00000414706 / NM_001044388.2; = p.E56* on NM_024341.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 234/610 reads (38%) | called by muse, varscan2
- ATP1A3 | c.1923C>T p.N641= (on ENST00000545399 / NM_001256214.2; = p.N628= on NM_152296.5) | Silent (SNP) | VAF 358/794 reads (45%) | catalogued as rs144130986; ClinVar: likely benign; called by muse, varscan2
- CP | c.261G>A p.P87= | Silent (SNP) | VAF 166/242 reads (69%) | catalogued as rs142440055; called by muse, varscan2
- FAM98C | c.717T>C p.T239= | Silent (SNP) | VAF 157/494 reads (32%) | called by muse, varscan2
- MAST3 | c.2943C>T p.H981= | Silent (SNP) | VAF 118/546 reads (22%) | catalogued as rs748598109; called by muse, varscan2
- PSG3 | c.1260A>G p.G420= | Silent (SNP) | VAF 250/494 reads (51%) | called by muse, varscan2
- TMEM171 | c.453C>T p.G151= | Silent (SNP) | VAF 189/653 reads (29%) | catalogued as rs373360645; called by muse, varscan2
- ABCF3 | c.-90C>A | 5'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, varscan2
- PNP | c.182-61A>T | Intron (SNP) | VAF 48/111 reads (43%) | called by muse, varscan2
- SPIRE1 | c.*33_*34dup | 3'UTR (INS) | VAF 72/195 reads (37%) | called by pindel, varscan2
- TRIM7 | c.849+42G>A | Intron (SNP) | VAF 134/252 reads (53%) | catalogued as rs1442337013; called by muse, varscan2
- ZNF417 | c.*39G>A | 3'UTR (SNP) | VAF 42/122 reads (34%) | catalogued as rs373416762; called by muse, varscan2
